Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5200, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5200-01A (Primary Tumor).

[page 1 of 3]
Patient Name:

Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Right upper pole renal mass.

TCGA - BP - 5200

Specimens Submitted:

1: Kidney, right, partial nephrectomy

DIAGNOSIS:

1. Kidney, right, partial nephrectomy:

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type
with focal sarcomatoid features and large areas of necrosis

Fuhrman Nuclear Grade:

Nuclear grade IV/IV

Tumor Size:

Greatest diameter is 7.5 cm.

Local Invasion (for renal cortical types):

Extends into renal pelvis

Renal Vein Invasion:

Not identified

No definite small vessel angiolymphatic invasion is identified.

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Focal interstitial chronic inflammation

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT2 Tumor >7.0 cm in greatest dimension limited to the kidney

Comment: Immunostains for carbonic anhydrase-IX (CA-IX) and CD10 show diffuse positivity in the tumor, whereas CK7 is negative. The immunoprofile supports the above interpretation.

[page 2 of 3]
REPORT

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Result	Special Stain	Comment
	CA-1X.	
	CD10	
	CK7	
	CA-1X.	
	CD10	
	CK7	
	RECUT	
	IMM RECUT	
	NEG CONT	
	IMM RECUT	
	NEG CONT	

Gross Description:

1). The specimen is received fresh for frozen section and is labeled "right renal tumor". It consists of a 9 x 8 x 5 cm wedge segment of kidney with a suture marking the deep margin. The margin is inked black and the specimen is serially sectioned to reveal a circumscribed necrotic yellow hemorrhagic, focally sclerotic mass measuring 7.5 x 6.0 x 5.7 cm. The clearance from the resection margin is 0.4 cm. Representative sections of the nearest margin and the tumor are submitted for frozen section diagnosis. Representatively submitted. Portions of the tumor are submitted for TPS.

Summary of sections:

FSC - frozen section control A
FSC B - frozen section control B
TM - tumor with margin
TC - tumor with capsule
T - representative sections of tumor

Summary of Sections:

Part 1: Kidney, right, partial nephrectomy

Block	Sect. Site	PCs
1	fsc	1
1	fsc b	1
6	t	6
3	tc	3
3	tm	3

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: Right renal tumor TUMOR WITH SPINDLE AND EPITHELIOID FEATURES, DEFER. AREA MARKED BY STITCH IS BENIGN. PERMANENT DIAGNOSIS: SAME

[page 3 of 3]
[REDACTED]

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 3bb97f53-96f9-4210-8b90-f6604089d9ba (TCGA-BP-5200.DD8C8F28-5614-4EF9-A19B-18A4A891B10A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).